Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OR, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OR-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M

PROCEDURE: SPHS

Source of Specimen: Esophagus. Esophageal cancer - adenocarcinoma. No chemo or radiation. No metastasis. Operative Procedure/Tissue Submitted: Transhiatal esophagectomy, jejunostomy, possible medial stenotomy, partial sternal split.

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: esophagus, distal third
C15.5

PROCEDURE: SPGD

1. "Distal esophagus and proximal stomach." Received in formalin in a large container is a transhiatal esophagectomy specimen consisting of: Distal esophagus (10.9 cm in length), proximal stomach (4.0 cm in length) and attached perigastric adipose. Both the adventitial and serosal surfaces are unremarkable. There is a 5.3 x 5.1 cm, well-demarcated area of tan, nodular, thickened and ulcerated mucosa located within the distal esophagus. This area comes to within 5.5 cm of the proximal margin, 0.1 cm of the GE junction and 3.0 cm of the distal margin. This area is 100% circumferential and upon sectioning contains a greatest wall thickness of 1.2 cm. A depth of invasion cannot be determined grossly. The surrounding, uninvolved esophageal mucosa is within the distal aspect and is focally dark brown, patchy and velvety in appearance. The remaining, uninvolved proximal esophageal mucosa and gastric mucosa are unremarkable. Multiple possible lymph nodes are identified up to 0.8 cm in greatest dimension.

1A-E. Irregular area of nodular mucosa, with thickest wall is A-C.

1F. JE junction.

1G. Six possible lymph nodes submitted whole.

1H. Four possible lymph nodes submitted whole.

2. "Cervical esophageal margin." Received in formalin in a small container is a 0.5 cm in length segment of unoriented esophagus. The specimen contains one stapled end and one opened end. Both the adventitial and mucosal surfaces are unremarkable. Submitted whole, staple end en face. (1 cassette
Staple line retained.

3. "Paraesophageal lymph node." Received in formalin in a small container is a 1.3 x 0.6 x 0.4 cm, tan lymph node. Serially sectioned. (1 cassette

4. "Perigastric lymph node." Received in formalin in a small container is a 0.6 x 0.5 x 0.5 cm lymph node with attached adipose. Bisected. (1 cassette

PROCEDURE: SPMI

ESOPHAGUS CARCINOMA

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

LOCATION: Lower

SIZE: 5.3 cm

HAS IT BEEN TREATED PREOPERATIVELY: No

TYPE OF CARCINOMA: Adenocarcinoma arising in Barrett's mucosa

DEPTH OF INVASION: Submucosa

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/12

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T1 NO Mx

PROCEDURE: SPDX

1. Distal esophagus and proximal stomach, resection: Invasive adenocarcinoma (5.3 cm) extending into submucosa. Margins negative. Ten lymph nodes negative for metastatic carcinoma. Background high grade Barrett's mucosa. Please see template.

2. Cervical esophagus, margin: Negative for carcinoma.

3. Paraesophageal lymph node, resection: One lymph node negative for metastatic carcinoma.

4. Perigastric lymph node, resection: One lymph node negative for carcinoma.

I, [redacted] signing staff pathologist, have personally examined and interpreted the slides from this case.

I/PAA Discrepancy		

Source: NCI Genomic Data Commons file ec4053d1-ee80-461a-86f9-cbd94fb6a175 (TCGA-L5-A4OR.6D467A2D-FC4E-49EB-81A9-FEB295D3DEA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).